Somatic mutation profile of tumor specimen TARGET-10-PAPFBR-09A (aliquot TARGET-10-PAPFBR-09A-01D) from TARGET case TARGET-10-PAPFBR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,042 days).
Specimen TARGET-10-PAPFBR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a0c4a0a-0a76-4812-ac45-b3f59de74541.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFBR-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFBR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b5b1e66-6237-4f89-a761-9e769ff871f8

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM15 | c.343-3C>A | Splice Region (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MYH2 | c.1049T>A p.V350D | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TPH1 | c.563A>C p.H188P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EDNRA | c.168T>C p.N56= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- GPR158 | c.2892G>A p.A964= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as rs200864072, COSV66265055; called by muse, mutect2, varscan2
- PACSIN1 | c.1167C>T p.R389= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs754027032; called by muse, mutect2
- RETREG1 | c.*90A>T | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
